TCGA case TCGA-AX-A06D — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/905291b0-f077-48f7-9c14-5cfa9d8a3e6e

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 82 years; Vital status: Dead; Days to death: 373 days (1.0 years).

Diagnoses (3)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 82.2 years (30,024 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; FIGO stage: Stage IIIA; FIGO staging edition year: 1988; Tumor grade: G2; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 50.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 7.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 3.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 53 days; Prescribed dose: 5; Prescribed dose units: AUC.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Ziv-Aflibercept; Initial disease status: Progressive Disease; Days to treatment start: 293 days; Days to treatment end: 293 days; Number of cycles: 1; Treatment dose: 327 mg; Prescribed dose: 4; Prescribed dose units: mg/kg; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Timepoint category: Prior to Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the breast (histology not recorded by GDC).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Letrozole; Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Tamoxifen; Treatment anatomic sites: Body, total.
3. Diagnosis record without a diagnosis name: Age at diagnosis: 82.9 years (30,277 days); Days to diagnosis: 253 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Day 253 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 373 days (1.0 years); Disease response: With Tumor.
- Peritoneal washing results: Positive; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Menopause status: Postmenopausal; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 91 kg; Height: 160 cm; BMI: 35.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AX-A06D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 190 mg.
  Slide TCGA-AX-A06D-01A-01-TSA: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 60; Percent normal cells: 15; Percent necrosis: 25; Percent stromal cells: 5; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AX-A06D-01A-01-BSA: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AX-A06D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AX-A06D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form: History tamoxifen use: Former User; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Tumor status: With tumor; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: Vegf-trap; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Carboplatin & Paclitaxel.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug 1: Pharmaceutical therapy drug name: Tamoxifen x5 years then switched to Femara.
- Other malignancy form, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: Femara.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: systemic treatment given to the prior/other malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 373 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 373 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 253 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AX-A06D-01): tumor purity 0.88, ploidy 2.12, whole-genome doublings 0 (call status: legacy_call).
